Somatic mutation profile of tumor specimen C3L-07614-01 (aliquot CPT0483720006) from CPTAC case C3L-07614, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 74.6 years (27,248 days).
Specimen C3L-07614-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7acb8b7-4ec5-42c6-b23a-67af2d398f4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07614-31 (Blood Derived Normal), aliquot CPT0483870004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75e4126c-ebd3-4639-9cd2-5fb425630253

The open-access MAF lists 1,859 somatic variants for this specimen: 1,346 protein-altering or splice-affecting, 440 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 984, Silent 440, Frame Shift Del 204, Frame Shift Ins 64, Nonsense Mutation 62, Intron 41, In Frame Del 14, 3'Flank 9, Splice Site 9, 5'Flank 7, 5'UTR 7, 3'UTR 7.

Variants (750 of 1,859; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.662dup p.G222Wfs*10 | Frame Shift Ins (INS) | VAF 33/224 reads (15%) | catalogued as rs769948289; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CAPN3 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs863224956, CM129344, CM990311, COSV58826312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 30/200 reads (15%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 50/307 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GLMN | c.743dup p.L248Ffs*14 | Frame Shift Ins (INS) | VAF 16/156 reads (10%) | catalogued as rs754756178; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2A | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 41/256 reads (16%) | catalogued as rs1555034779, COSV100627800; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.14710C>T p.R4904* | Nonsense Mutation (SNP) | VAF 63/434 reads (15%) | catalogued as rs398123721, CM105476, COSV56414273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 39/259 reads (15%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 20/184 reads (11%) | hotspot (GDC flag); catalogued as CS1413088, COSV64290834, COSV64293694, COSV64298429; called by muse, mutect2, varscan2
- PTH1R | c.668A>G p.H223R | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs121434597, CM951089; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.11320del p.A3774Rfs*8 | Frame Shift Del (DEL) | VAF 59/406 reads (15%) | catalogued as rs768698639, CM073325, COSV100614110; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SHANK2 | c.1896dup p.D633Rfs*3 | Frame Shift Ins (INS) | VAF 40/290 reads (14%) | catalogued as rs1555013332; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AARD | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 74/618 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.121); catalogued as rs374262247; called by mutect2, varscan2
- ABCB8 | c.1033C>T p.R345C (on ENST00000297504 / NM_001282291.2; = p.R328C on NM_007188.5) | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754606258, COSV52502008; called by muse, mutect2, varscan2
- ABCC1 | c.4084G>A p.G1362S | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768426028; called by muse, mutect2, varscan2
- AC025287.4 | c.279dup p.H94Tfs*101 | Frame Shift Ins (INS) | VAF 61/388 reads (16%) | catalogued as rs1190364865; called by mutect2, pindel, varscan2
- ACADSB | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV62550519; called by muse, mutect2
- ACO2 | c.1819C>A p.R607S | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as CM165651, COSV53442569; called by muse, mutect2, varscan2
- ACOT11 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 78/466 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754487008, COSV59345955; called by muse, mutect2, varscan2
- ACSS3 | c.131del p.G44Afs*27 | Frame Shift Del (DEL) | VAF 68/562 reads (12%) | catalogued as COSV99039028, COSV99698537; called by mutect2, pindel, varscan2
- ADAD2 | c.568del p.Q190Rfs*11 (on ENST00000315906 / NM_001145400.2; = p.Q262Rfs*11 on NM_139174.4) | Frame Shift Del (DEL) | VAF 69/516 reads (13%) | catalogued as rs1390126889; called by mutect2, pindel, varscan2
- ADAM21 | c.2051del p.L684Cfs*3 | Frame Shift Del (DEL) | VAF 60/345 reads (17%) | catalogued as rs546931496; called by mutect2, varscan2
- ADAM29 | c.2186C>A p.P729H | Missense Mutation (SNP) | VAF 55/405 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.425); catalogued as COSV63664633; called by muse, mutect2, varscan2
- ADAMTS12 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61277989; called by muse, mutect2, varscan2
- ADCY1 | c.1306G>T p.G436W | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99813140; called by muse, mutect2, varscan2
- ADCY4 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs756925041, COSV60251947; called by muse, mutect2, varscan2
- ADGRF2 | c.1364G>A p.G455D (on ENST00000296862 / NM_001368115.2; = p.G387D on NM_153839.7) | Missense Mutation (SNP) | VAF 56/370 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57286179; called by muse, mutect2, varscan2
- ADGRL3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs767628272; called by muse, mutect2, varscan2
- ADH7 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs539728659, COSV52922169; called by muse, mutect2, varscan2
- ADIPOR2 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as rs1321520886, COSV100840004; called by muse, mutect2, varscan2
- AFTPH | c.1859C>T p.T620M | Missense Mutation (SNP) | VAF 67/435 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs764819647, COSV99480789; called by muse, mutect2, varscan2
- AGO2 | c.2201C>T p.T734M | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766748578, COSV99596072; called by muse, mutect2, varscan2
- AGRN | c.3065C>T p.S1022L | Missense Mutation (SNP) | VAF 54/478 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs777916390, COSV65072734; called by muse, varscan2
- AGTR2 | c.401T>G p.F134C | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100903575, COSV100903639; called by muse, mutect2, varscan2
- AHRR | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 78/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1282181619, COSV57085921; called by muse, mutect2, varscan2
- AHSA1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs923918665; called by muse, mutect2
- AK5 | c.493G>A p.E165K (on ENST00000354567 / NM_174858.3; = p.E139K on NM_012093.4) | Missense Mutation (SNP) | VAF 30/329 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100481295; called by muse, mutect2
- AKAP11 | c.380T>C p.M127T | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1483286373; called by muse, mutect2, varscan2
- AKAP17A | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 98/686 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs771781177; called by muse, varscan2
- AKR1B10 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1488126019; called by muse, mutect2
- ALDH18A1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 62/356 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs777991529, COSV100973201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.4243C>T p.P1415S | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV66595938; called by muse, mutect2, varscan2
- ALKBH4 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 83/611 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV52961028; called by muse, mutect2, varscan2
- AMPD3 | c.395G>A p.R132Q (on ENST00000396553 / NM_001025389.2; = p.R141Q on NM_000480.3) | Missense Mutation (SNP) | VAF 57/378 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs748652391; called by muse, mutect2, varscan2
- ANAPC1 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs1159635391; called by muse, mutect2, varscan2
- ANGEL2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765456910, COSV64738158; called by muse, mutect2, varscan2
- ANGPTL5 | c.1130T>C p.M377T | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57533160; called by muse, mutect2, varscan2
- ANKFY1 | c.1682T>C p.V561A | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.761); catalogued as rs1242324695; called by muse, mutect2
- ANKRD11 | c.5587G>A p.D1863N | Missense Mutation (SNP) | VAF 77/473 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs769501359; called by muse, mutect2, varscan2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 34/272 reads (13%) | catalogued as rs868780344; called by mutect2, varscan2
- ANKRD18B | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 50/489 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1230574270, COSV99340276; called by muse, mutect2, varscan2
- ANKRD30B | c.584del p.N195Mfs*26 | Frame Shift Del (DEL) | VAF 30/266 reads (11%) | catalogued as rs1207049839; called by mutect2, pindel, varscan2
- ANKRD34C | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as rs971080019; called by muse, mutect2, varscan2
- ANKRD36B | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1265104498; called by muse, mutect2, varscan2
- ANLN | c.207dup p.R70Tfs*4 | Frame Shift Ins (INS) | VAF 38/260 reads (15%) | catalogued as rs1232253883; called by mutect2, varscan2
- ANO2 | c.1003C>T p.R335C (on ENST00000356134 / NM_001278597.3; = p.R339C on NM_001278596.3) | Missense Mutation (SNP) | VAF 43/310 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs372991029, COSV59050232; called by muse, mutect2, varscan2
- ANO9 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 59/476 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs375820320; called by muse, mutect2, varscan2
- ANTXR1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.752); catalogued as rs754833587, COSV58023650; called by muse, mutect2, varscan2
- ANXA1 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 18/181 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs570755224, COSV57411064; called by muse, mutect2, varscan2
- AOC1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 78/567 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs370764836; called by muse, mutect2, varscan2
- AP1G2 | c.1345del p.A449Pfs*84 | Frame Shift Del (DEL) | VAF 65/393 reads (17%) | catalogued as rs749982998; called by mutect2, pindel, varscan2
- AP2A2 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 76/587 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs897441801; called by muse, mutect2, varscan2
- APBA1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 105/660 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55223471; called by muse, varscan2
- APBB1IP | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs1191010173; called by muse, mutect2, varscan2
- APOE | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52986441; called by muse, mutect2, varscan2
- ARFRP1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200507208; called by muse, mutect2, varscan2
- ARHGAP24 | c.893G>A p.R298H (on ENST00000395184 / NM_001025616.3; = p.R205H on NM_031305.3) | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1007199761, COSV51988098; called by muse, mutect2, varscan2
- ARHGEF18 | c.2531C>T p.A844V (on ENST00000359920 / NM_001130955.2; = p.A740V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/631 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs754269396; called by muse, mutect2, varscan2
- ARHGEF5 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761638420; called by mutect2, varscan2
- ARID1A | c.941del p.G314Afs*49 | Frame Shift Del (DEL) | VAF 107/671 reads (16%) | catalogued as rs1415214478; called by mutect2, pindel, varscan2
- ARID1B | c.2658G>A p.M886I | Missense Mutation (SNP) | VAF 63/476 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as rs1060499843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID2 | c.4124del p.N1375Tfs*11 | Frame Shift Del (DEL) | VAF 42/314 reads (13%) | catalogued as COSV57613197; called by mutect2, pindel, varscan2
- ARSA | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 74/673 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs774085931; called by muse, mutect2, varscan2
- ART1 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 76/604 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99167219; called by muse, mutect2, varscan2
- ASB18 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 65/488 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1346201314; called by muse, mutect2, varscan2
- ASH2L | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV99166916; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 49/204 reads (24%) | catalogued as rs747712363; called by mutect2, varscan2
- ATAD2B | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53198340; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 64/412 reads (16%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATAD3A | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 71/442 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as rs779111850, COSV59234862; called by muse, mutect2, varscan2
- ATF3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 39/303 reads (13%) | catalogued as rs756952643, COSV58378340; called by muse, mutect2, varscan2
- ATG2A | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201903243; called by muse, mutect2, varscan2
- ATP13A2 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs371772922; called by muse, mutect2, varscan2
- ATP1A3 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 32/357 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs782717626; called by muse, mutect2
- ATP2A3 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs752821434; called by muse, mutect2, varscan2
- ATP5F1A | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as rs761252563; called by muse, mutect2, varscan2
- ATP5MGL | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 56/422 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV100677833; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs761913726, COSV57749833; called by muse, mutect2, varscan2
- ATP6V0E2 | c.229C>T p.R77C (on ENST00000425642; = p.R126C on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/453 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs570061729, COSV70416782; called by muse, mutect2, varscan2
- ATP8A2 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1349352729, COSV54945493; called by muse, varscan2
- AUTS2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 69/532 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1359937867, COSV61429769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GLCT | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs114543272; called by muse, mutect2, varscan2
- B4GALT2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 48/355 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs147797915; called by muse, mutect2, varscan2
- B9D2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.441); catalogued as rs1224741304; called by muse, mutect2
- BARHL1 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 57/518 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs752993753, COSV55036962; called by muse, mutect2, varscan2
- BCAN | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 80/546 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753351484, COSV61256276; called by muse, mutect2, varscan2
- BCL11A | c.2197G>A p.E733K (on ENST00000335712 / NM_001365609.1; = p.E767K on NM_022893.4) | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59634015; called by muse, mutect2, varscan2
- BMP5 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs868777976, COSV63703310; called by muse, mutect2, varscan2
- BNIP5 | c.1702dup p.Y568Lfs*24 | Frame Shift Ins (INS) | VAF 50/273 reads (18%) | catalogued as rs747868798; called by mutect2, varscan2
- BNIPL | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 59/297 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.387); catalogued as rs756275551; called by muse, mutect2, varscan2
- BRD8 | c.3124del p.E1042Rfs*52 | Frame Shift Del (DEL) | VAF 31/216 reads (14%) | catalogued as COSV54731723; called by mutect2, pindel, varscan2
- C10orf71 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs374875968; called by muse, mutect2, varscan2
- C11orf94 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 67/441 reads (15%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs376457105; called by muse, mutect2, varscan2
- C11orf96 | c.1259G>A p.C420Y (on ENST00000339446; = p.C107Y on NM_001145033.2) | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV59708049; called by muse, mutect2, varscan2
- C1orf87 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1236745552, COSV64596108; called by muse, mutect2, varscan2
- C2orf78 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758443703; called by muse, mutect2, varscan2
- C6orf132 | c.3289G>A p.G1097R | Missense Mutation (SNP) | VAF 83/587 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1248852340; called by muse, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 22/174 reads (13%) | catalogued as rs747591930; called by mutect2, varscan2
- CACNA1F | c.1805G>A p.C602Y | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782273072; called by muse, mutect2, varscan2
- CADPS2 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs772668227, COSV57363742; called by muse, mutect2, varscan2
- CAND2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs549612663, COSV99929156; called by muse, varscan2
- CARD9 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 67/461 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772249417, COSV53738140; called by muse, mutect2, varscan2
- CARNS1 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 84/571 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535216231, COSV100321816; called by muse, mutect2, varscan2
- CAVIN4 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1332922647; called by muse, mutect2, varscan2
- CCDC116 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141137219; called by muse, mutect2, varscan2
- CCDC144A | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 39/576 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs530070283; called by muse, mutect2
- CCDC168 | c.6356del p.N2119Tfs*6 | Frame Shift Del (DEL) | VAF 39/273 reads (14%) | catalogued as rs1349277202; called by mutect2, pindel, varscan2
- CCDC168 | c.3133G>T p.D1045Y | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs773350442; called by muse, mutect2, varscan2
- CCDC175 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755841941; called by muse, varscan2
- CCDC7 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 53/321 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.748); catalogued as rs368403420; called by muse, mutect2, varscan2
- CCZ1B | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as rs1308684437, COSV57436577, COSV57439917; called by muse, mutect2, varscan2
- CD5L | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV63821180; called by muse, mutect2, varscan2
- CDC27 | c.182T>C p.L61S | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50437512; called by muse, mutect2, varscan2
- CDC42BPB | c.4468C>T p.R1490C | Missense Mutation (SNP) | VAF 57/373 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs1194354927, COSV63475680; called by muse, mutect2, varscan2
- CDH26 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723314; called by muse, mutect2, varscan2
- CDIPT | c.589G>C p.A197P | Missense Mutation (SNP) | VAF 61/463 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54889223; called by muse, mutect2, varscan2
- CELSR2 | c.8153C>T p.T2718M | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs762010127; called by muse, mutect2, varscan2
- CENPU | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 65/487 reads (13%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.009); catalogued as COSV55658845, COSV99860026; called by muse, mutect2, varscan2
- CEP192 | c.3745G>A p.A1249T | Missense Mutation (SNP) | VAF 61/509 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs753523783, COSV58060783; called by muse, mutect2, varscan2
- CEP290 | c.5860G>A p.D1954N | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as rs368197113; called by muse, mutect2, varscan2
- CEP72 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs3209487; called by muse, mutect2, varscan2
- CERK | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs779486682; called by muse, mutect2, varscan2
- CFAP52 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs566597331, COSV99556422; called by muse, mutect2, varscan2
- CFAP61 | c.1918G>A p.V640I | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.391); catalogued as COSV55622091; called by muse, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 73/525 reads (14%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFAP65 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 59/526 reads (11%) | SIFT deleterious, low confidence (0.02); catalogued as rs376689400, COSV55392313; called by muse, mutect2, varscan2
- CFL1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV57379179; called by muse, mutect2, varscan2
- CHRM1 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 73/483 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61007020; called by muse, mutect2, varscan2
- CHRNA4 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 84/584 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs150336658; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- CHST13 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 90/557 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); catalogued as rs1434019449; called by muse, mutect2, varscan2
- CIC | c.4790del p.P1597Hfs*23 | Frame Shift Del (DEL) | VAF 39/269 reads (14%) | catalogued as rs1158987717, COSV50583567; called by mutect2, pindel, varscan2
- CIITA | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 73/488 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); catalogued as rs1248790122; called by muse, mutect2, varscan2
- CILP2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 219/712 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747547566, COSV52272864; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs752250702; called by mutect2, varscan2
- CKAP4 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 78/427 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1196001991; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 42/310 reads (14%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLEC17A | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs199539924, COSV60427075; called by muse, mutect2, varscan2
- CLIP2 | c.2462C>T p.T821M | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782465626, COSV56275416; called by muse, mutect2
- CLTC | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs748314755, COSV52249389; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 23/185 reads (12%) | catalogued as rs758676375; called by mutect2, varscan2
- COBL | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148062130; called by muse, mutect2, varscan2
- COL15A1 | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 32/448 reads (7%) | catalogued as rs1255093188; called by muse, mutect2
- COL1A2 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51954486, COSV51962001; called by muse, mutect2
- COL5A3 | c.3139C>A p.P1047T | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV53409201; called by muse, mutect2, varscan2
- COL6A2 | c.1815C>T p.C605= | Splice Region (SNP) | VAF 33/504 reads (7%) | catalogued as rs778401356, COSV56012911; ClinVar: uncertain significance; called by muse, mutect2
- COL6A3 | c.3893C>T p.A1298V | Missense Mutation (SNP) | VAF 82/447 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs570869775, COSV55090929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A3 | c.1485dup p.G496Rfs*105 | Frame Shift Ins (INS) | VAF 79/684 reads (12%) | catalogued as rs1206877805; called by mutect2, pindel, varscan2
- CORO1A | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 57/407 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs763170903, COSV54630566; called by muse, mutect2, varscan2
- CPAMD8 | c.269C>T p.A90V (on ENST00000651564; = p.A43V on NM_015692.5) | Missense Mutation (SNP) | VAF 79/322 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs201146129, COSV52241350; called by muse, mutect2, varscan2
- CPEB1 | c.1472C>T p.T491M (on ENST00000617958; = p.T426M on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/539 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375054209; called by muse, mutect2, varscan2
- CRB2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs763849885; called by muse, varscan2
- CREB5 | c.920A>G p.H307R (on ENST00000357727 / NM_182898.4; = p.H300R on NM_004904.3) | Missense Mutation (SNP) | VAF 87/657 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV63221696; called by muse, mutect2, varscan2
- CSMD2 | c.6157G>A p.E2053K | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs1318882966; called by muse, mutect2, varscan2
- CSRNP2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV50396925; called by muse, mutect2, varscan2
- CTDP1 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 250/739 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs987596579, COSV50005802; called by muse, mutect2, varscan2
- CYBB | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.183); catalogued as CM1313103; called by muse, mutect2, varscan2
- DAB1 | c.1456G>A p.A486T (on ENST00000371231; = p.A453T on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/458 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs546641246; called by muse, mutect2, varscan2
- DAPK1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 72/530 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375598719; called by muse, mutect2, varscan2
- DCT | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs376196399; called by muse, mutect2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 44/310 reads (14%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX24 | c.2114C>T p.T705M | Missense Mutation (SNP) | VAF 62/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs779313699; called by muse, mutect2, varscan2
- DDX28 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 81/476 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1264028695; called by muse, mutect2, varscan2
- DDX51 | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774667409; called by muse, mutect2, varscan2
- DES | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 76/596 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.651); catalogued as rs868853251, COSV64660712; called by muse, mutect2, varscan2
- DHDH | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 74/450 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs763168931; called by muse, mutect2, varscan2
- DHX36 | c.1385T>C p.I462T | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs763875729; called by muse, mutect2, varscan2
- DHX37 | c.1930C>T p.R644C | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750227236, COSV58135685; called by muse, mutect2, varscan2
- DHX38 | c.407_408del p.E136Afs*29 | Frame Shift Del (DEL) | VAF 37/332 reads (11%) | catalogued as rs1376393495; called by pindel, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 40/208 reads (19%) | catalogued as rs749610132; called by mutect2, varscan2
- DLGAP4 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 79/544 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs192489219; called by muse, mutect2, varscan2
- DNAAF4 | c.330_331del p.R110Sfs*27 | Frame Shift Del (DEL) | VAF 43/376 reads (11%) | catalogued as rs748362263; called by pindel, varscan2
- DNAH11 | c.3611G>A p.G1204D | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as rs1258102150; called by muse, mutect2
- DNAH11 | c.5176G>A p.E1726K | Missense Mutation (SNP) | VAF 44/376 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs373580829, COSV60957278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.1916C>A p.P639Q | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1255368694, COSV51135614, COSV51141750; called by muse, mutect2
- DNAJC16 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.195); catalogued as rs150982165; called by muse, mutect2, varscan2
- DNHD1 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 60/431 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1010210418, COSV99600063; called by muse, mutect2, varscan2
- DNMT3A | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs755982635, COSV53065667, COSV99262397; called by muse, mutect2, varscan2
- DNMT3B | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 61/396 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1267164985, COSV52416625, COSV52424854; called by muse, mutect2, varscan2
- DOCK3 | c.5942G>A p.R1981H | Missense Mutation (SNP) | VAF 88/562 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs782455185; called by muse, mutect2, varscan2
- DOCK4 | c.3352A>G p.M1118V | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs752493522; called by muse, mutect2
- DOCK5 | c.4675G>A p.V1559I | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs756518291, COSV52396868; called by muse, mutect2, varscan2
- DOCK5 | c.5084G>A p.G1695E | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs770555269; called by muse, mutect2, varscan2
- DOCK6 | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 162/482 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1342612871; called by muse, mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 34/241 reads (14%) | catalogued as rs35482889; called by mutect2, varscan2
- DPEP2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs867172890; called by muse, mutect2, varscan2
- DPP9 | c.397C>T p.R133C (on ENST00000598800; = p.R162C on NM_139159.5) | Missense Mutation (SNP) | VAF 139/440 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774328255; called by muse, mutect2, varscan2
- DPY19L1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60581641; called by muse, mutect2, varscan2
- DPY19L3 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs1401664741, COSV99046021; called by muse, mutect2, varscan2
- DRG2 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 55/358 reads (15%) | catalogued as rs974984848, COSV56728780; called by muse, mutect2, varscan2
- DSEL | c.3078dup p.Q1027Sfs*28 | Frame Shift Ins (INS) | VAF 70/495 reads (14%) | catalogued as rs762694026; called by mutect2, varscan2
- DSG3 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 66/896 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs893360840; called by muse, mutect2
- DTWD1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766234751, COSV52073316; called by muse, mutect2
- DYNC1H1 | c.12982G>A p.E4328K | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270150920; called by muse, mutect2, varscan2
- DYRK1B | c.1633dup p.Q545Pfs*30 | Frame Shift Ins (INS) | VAF 56/422 reads (13%) | catalogued as rs775499198; called by mutect2, varscan2
- DYRK1B | c.1058del p.G353Vfs*150 | Frame Shift Del (DEL) | VAF 69/454 reads (15%) | catalogued as rs757658083; called by mutect2, pindel, varscan2
- DYRK3 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 90/455 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs782131237, COSV65607022; called by muse, mutect2, varscan2
- DYSF | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as rs759171890, COSV50266531, COSV50543698; ClinVar: uncertain significance; called by muse, varscan2
- EDIL3 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772124861; called by muse, mutect2, varscan2
- EFCAB5 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs201514253, COSV57931698; called by muse, mutect2, varscan2
- EGFR | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 71/611 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs770193776, COSV51771628; called by muse, mutect2, varscan2
- EID2B | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 107/644 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1173706912, COSV100410972; called by muse, mutect2, varscan2
- EML2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774518149, COSV55599485; called by muse, mutect2, varscan2
- ENPP4 | c.628del p.I210* | Frame Shift Del (DEL) | VAF 36/350 reads (10%) | catalogued as rs756006851; called by mutect2, pindel
- EPB41L3 | c.2170del p.T724Lfs*5 | Frame Shift Del (DEL) | VAF 39/312 reads (13%) | catalogued as COSV59457005; called by mutect2, pindel, varscan2
- EPC2 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774665912; called by muse, mutect2, varscan2
- EPG5 | c.4597G>A p.A1533T | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs374899586; called by muse, mutect2, varscan2
- EPHA3 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60715048; called by muse, mutect2, varscan2
- EPHB1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs533462328, COSV67662549; called by muse, mutect2, varscan2
- EPHX2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1437846757; called by muse, varscan2
- EPN2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.242); catalogued as rs772339828, COSV59062415; called by muse, varscan2
- EPN3 | c.1152del p.T385Pfs*7 | Frame Shift Del (DEL) | VAF 72/610 reads (12%) | catalogued as rs760519306; called by mutect2, pindel, varscan2
- ERBB3 | c.1479C>T p.C493= | Splice Region (SNP) | VAF 26/179 reads (15%) | catalogued as rs754618467; called by muse, mutect2, varscan2
- ERC2 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as rs184223678; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 78/556 reads (14%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERMP1 | c.2326C>T p.R776* | Nonsense Mutation (SNP) | VAF 36/316 reads (11%) | catalogued as rs765626934, COSV53039070; called by muse, varscan2
- ERVK3-1 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs886777609; called by muse, mutect2, varscan2
- ESCO1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 29/345 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs762170421; called by muse, mutect2
- EVA1A | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs560233570, COSV52057908; called by muse, mutect2, varscan2
- EXOC4 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.728); catalogued as COSV54127002; called by muse, mutect2, varscan2
- EZH2 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 54/349 reads (15%) | catalogued as rs1169410711, COSV57446240, COSV57461859; called by muse, mutect2, varscan2
- F5 | c.585del p.T197Pfs*2 | Frame Shift Del (DEL) | VAF 22/190 reads (12%) | catalogued as CD034471; called by mutect2, pindel, varscan2
- FAM13C | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53252131; called by muse, mutect2, varscan2
- FAM160B2 | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370606615; called by muse, mutect2
- FAM20A | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 44/672 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101646487; called by muse, mutect2
- FANCE | c.929del p.P310Qfs*54 | Frame Shift Del (DEL) | VAF 43/333 reads (13%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, pindel, varscan2
- FAT3 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs376399512; called by muse, mutect2, varscan2
- FBLIM1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 108/655 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as rs758813348; called by muse, mutect2, varscan2
- FBLN2 | c.2186C>T p.T729M | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs368591685; called by muse, mutect2, varscan2
- FBN3 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs768162766; called by muse, mutect2, varscan2
- FBRS | c.904C>T p.R302W (on ENST00000287468; = p.R822W on NM_001105079.3) | Missense Mutation (SNP) | VAF 83/529 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1249010859, COSV54916258; called by muse, mutect2, varscan2
- FBRSL1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 48/750 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs963680128, COSV99905010; called by muse, mutect2
- FBRSL1 | c.2739del p.A914Pfs*90 | Frame Shift Del (DEL) | VAF 46/290 reads (16%) | catalogued as rs1566257864; called by mutect2, varscan2
- FGD2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs367888863; called by muse, mutect2, varscan2
- FGD5 | c.3760G>A p.D1254N | Missense Mutation (SNP) | VAF 54/393 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs753390245; called by muse, mutect2, varscan2
- FGD6 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 64/319 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1281269436, COSV59692731; called by muse, mutect2, varscan2
- FLRT3 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 47/477 reads (10%) | catalogued as rs1486368839, COSV53970142, COSV99428675; called by muse, mutect2
- FOXO3 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752765431, COSV59631110; called by muse, mutect2, varscan2
- FRAS1 | c.9601C>G p.P3201A | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV53601715; called by muse, mutect2, varscan2
- FREM1 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 43/264 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV66528474, COSV66531750; called by muse, mutect2, varscan2
- FRMD7 | c.1492del p.Y498Mfs*26 | Frame Shift Del (DEL) | VAF 66/226 reads (29%) | catalogued as CD087853, CD118788; called by mutect2, varscan2
- FRMD7 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.953); catalogued as COSV53745587; called by muse, mutect2, varscan2
- FSIP2 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480074726; called by muse, mutect2, varscan2
- FUT6 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 65/442 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761897122; called by muse, mutect2, varscan2
- GALC | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs1349064845, CM162981, COSV54325865; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT17 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 71/544 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61148446; called by muse, mutect2, varscan2
- GALR1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 72/644 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs1292074385, COSV55316287; called by muse, mutect2
- GASK1A | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537741985; called by muse, mutect2, varscan2
- GATA3 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 92/601 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs778161799; called by muse, mutect2, varscan2
- GATA5 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 61/508 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs919823669; called by muse, mutect2, varscan2
- GFRA4 | c.601G>A p.V201I (on ENST00000319242 / NM_145762.3; = p.V171I on NM_022139.4) | Missense Mutation (SNP) | VAF 59/515 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs1256491017, COSV51774611; called by muse, varscan2
- GHITM | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs1216928773, COSV64538435; called by muse, mutect2, varscan2
- GIMAP1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 90/634 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs1345838972, COSV56187780; called by muse, mutect2, varscan2
- GIMAP6 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 55/529 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as rs375860624, COSV61034548; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 59/492 reads (12%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI3 | c.2867G>A p.R956H | Missense Mutation (SNP) | VAF 87/626 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV67884732; called by muse, mutect2, varscan2
- GPAA1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782442904; called by muse, varscan2
- GPAT4 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1167582807; called by muse, mutect2, varscan2
- GPC5 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 58/391 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65618429; called by muse, mutect2, varscan2
- GPER1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.438); catalogued as rs771368557, COSV99867235, COSV99867518; called by muse, mutect2, varscan2
- GPR135 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 45/660 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.05); catalogued as COSV67749674; called by muse, mutect2
- GPR15 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 33/321 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52520016; called by muse, mutect2, varscan2
- GPR157 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 42/327 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as COSV66233760; called by muse, mutect2, varscan2
- GPRC5B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 75/536 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs137970804; called by muse, mutect2, varscan2
- GRIK1 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187514184, COSV58731753; called by muse, mutect2, varscan2
- GRIN2D | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 96/582 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1281711096; called by muse, mutect2, varscan2
- GRM2 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56583567; called by muse, mutect2
- GRM5 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 55/436 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs1376561638; called by muse, mutect2, varscan2
- GSDMA | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 46/279 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs754816059, COSV56977327; called by muse, mutect2, varscan2
- GSDMC | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs377444902; called by muse, mutect2, varscan2
- H3C13 | c.121C>A p.R41S | Missense Mutation (SNP) | VAF 65/535 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs782255373; called by muse, mutect2
- H6PD | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753638476, COSV66230925; called by muse, varscan2
- HAND2 | c.247dup p.V83Gfs*260 | Frame Shift Ins (INS) | VAF 74/492 reads (15%) | catalogued as rs756064749; called by mutect2, varscan2
- HDGFL1 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 98/654 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.02); catalogued as rs1041727437, COSV100014555; called by muse, varscan2
- HDX | c.912G>T p.E304D | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52983361; called by muse, mutect2
- HECTD4 | c.6073G>A p.V2025I | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs774653504; called by muse, mutect2, varscan2
- HECW2 | c.4628G>A p.R1543H | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs781523022, COSV53672898; called by muse, mutect2, varscan2
- HELZ2 | c.6728G>A p.R2243H (on ENST00000467148 / NM_001037335.2; = p.R1674H on NM_033405.3) | Missense Mutation (SNP) | VAF 68/507 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200886569, COSV71296316; called by muse, mutect2, varscan2
- HERC2 | c.11255G>A p.R3752H | Missense Mutation (SNP) | VAF 83/542 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55350967; called by muse, mutect2, varscan2
- HGS | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 64/453 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454125209, COSV100230898; called by muse, mutect2, varscan2
- HID1 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs994473385, COSV100585993; called by muse, mutect2, varscan2
- HIF3A | c.1210G>A p.A404T (on ENST00000377670 / NM_152795.4; = p.A335T on NM_022462.4) | Missense Mutation (SNP) | VAF 82/549 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.657); catalogued as rs778919362, COSV99356107; called by muse, mutect2, varscan2
- HIVEP1 | c.7979C>T p.T2660M | Missense Mutation (SNP) | VAF 136/438 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs762472721, COSV101044627; called by muse, mutect2, varscan2
- HMGN5 | c.534del p.G179Vfs*48 | Frame Shift Del (DEL) | VAF 43/205 reads (21%) | catalogued as rs1556033122; called by mutect2, pindel, varscan2
- HOXD1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 84/536 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs746341936; called by muse, varscan2
- HS6ST3 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1318837136; called by muse, mutect2, varscan2
- HSPA6 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs779143167; called by muse, mutect2, varscan2
- HSPBAP1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778387110, COSV60242367; called by muse, mutect2, varscan2
- HTR1B | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV100885297; called by muse, mutect2, varscan2
- HTR2A | c.1212dup p.P405Tfs*18 | Frame Shift Ins (INS) | VAF 45/319 reads (14%) | catalogued as rs750816290; called by mutect2, pindel, varscan2
- IFFO1 | c.1089del p.R364Gfs*47 (on ENST00000396840 / NM_001330324.2; = p.R367Gfs*47 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/391 reads (14%) | catalogued as rs750779916, COSV60737300; called by mutect2, pindel, varscan2
- IFFO1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59114075; called by muse, mutect2, varscan2
- IFIT5 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 58/385 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs376725006; called by muse, mutect2, varscan2
- IFRD1 | c.916dup p.Y306Lfs*2 | Frame Shift Ins (INS) | VAF 38/217 reads (18%) | catalogued as rs979653918; called by mutect2, varscan2
- IGFALS | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 44/617 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236702; called by muse, mutect2
- IGHV3-16 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 68/430 reads (16%) | catalogued as rs782240233; called by mutect2, pindel, varscan2
- IGHV3-20 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); catalogued as rs566452326; called by muse, mutect2, varscan2
- IGLV3-22 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs374444373; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 56/222 reads (25%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- IL32 | c.385C>T p.R129* (on ENST00000396890 / NM_001308078.4; = p.R83* on NM_004221.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 29/386 reads (8%) | catalogued as rs757614578, COSV99145498; called by muse, mutect2
- IMPG2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1189940540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPG2 | c.814_816del p.E272del | In Frame Del (DEL) | VAF 30/202 reads (15%) | catalogued as rs777176327; called by pindel, varscan2
- INS | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 71/490 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM074283, COSV99171162; called by muse, mutect2, varscan2
- INTS1 | c.2527del p.R843Gfs*11 | Frame Shift Del (DEL) | VAF 34/254 reads (13%) | catalogued as rs779930616; called by mutect2, pindel, varscan2
- IPO5 | c.2153-1C>T p.X718_splice | Splice Site (SNP) | VAF 37/213 reads (17%) | catalogued as COSV99847671; called by muse, mutect2, varscan2
- IQCN | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 92/504 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs766759094; called by muse, mutect2, varscan2
- ITGA1 | c.3328C>T p.R1110W | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs779714917, COSV50878920; called by muse, mutect2, varscan2
- ITGAX | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200320931, COSV51643641; called by muse, mutect2, varscan2
- ITM2A | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs3180834; called by muse, mutect2, varscan2
- ITPR3 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1229568516; called by muse, mutect2, varscan2
- ITPR3 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs771869292, COSV100967983; called by muse, mutect2, varscan2
- JADE2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1200571794; called by muse, mutect2, varscan2
- JAKMIP3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1357363751; called by muse, mutect2, varscan2
- JMJD1C | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748501330, COSV67858357; called by muse, varscan2
- KATNIP | c.1394_1397del p.K465Rfs*3 | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | catalogued as rs1311633657; called by mutect2, pindel, varscan2
- KBTBD11 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1314465092; called by muse, mutect2
- KCND3 | c.1898del p.P633Lfs*13 | Frame Shift Del (DEL) | VAF 71/564 reads (13%) | catalogued as COSV56188292; called by mutect2, pindel, varscan2
- KCNG2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1194082093, COSV100301773; called by muse, mutect2, varscan2
- KCNH8 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751337521, COSV60474184; called by muse, mutect2, varscan2
- KCNK12 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 108/588 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59945108; called by muse, mutect2, varscan2
- KDM3B | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs370533044; called by muse, mutect2, varscan2
- KIAA1217 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 58/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368036126; called by muse, mutect2, varscan2
- KIAA1549 | c.4970C>T p.S1657L | Missense Mutation (SNP) | VAF 127/434 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747362005, COSV54314994; called by muse, mutect2, varscan2
- KIDINS220 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs376485014; called by muse, mutect2, varscan2
- KIF5C | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV101371332; called by muse, mutect2, varscan2
- KIFC3 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 51/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1361169981, COSV65550499; called by muse, mutect2, varscan2
- KIFC3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 65/450 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.197); catalogued as rs782139227; called by muse, mutect2, varscan2
- KLB | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 66/494 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs536465687; called by muse, mutect2, varscan2
- KLHL14 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 52/896 reads (6%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.806); catalogued as COSV63833921; called by muse, mutect2
- KMT2B | c.1656dup p.K553Qfs*46 | Frame Shift Ins (INS) | VAF 42/368 reads (11%) | catalogued as rs775294431; called by mutect2, varscan2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 82/543 reads (15%) | catalogued as COSV55868319; called by mutect2, pindel, varscan2
- KMT2C | c.14242G>A p.A4748T | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.9); catalogued as rs773125481, COSV51439978; called by muse, mutect2, varscan2
- KMT2C | c.7826G>A p.R2609Q | Missense Mutation (SNP) | VAF 49/532 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as rs746659124, COSV51455394; called by muse, mutect2
- KNG1 | c.1032del p.K344Nfs*6 | Frame Shift Del (DEL) | VAF 41/268 reads (15%) | catalogued as rs1318823203; called by mutect2, pindel, varscan2
- KRT18 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1311227284; called by muse, mutect2, varscan2
- KRT26 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV56971644; called by muse, mutect2, varscan2
- KRT72 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781213969; called by muse, mutect2, varscan2
- KSR1 | c.2008C>T p.R670W (on ENST00000644974 / NM_001367810.1; = p.R555W on NM_014238.2) | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759272239, COSV52032354; called by muse, mutect2, varscan2
- KTN1 | c.3302dup p.A1102Gfs*15 (on ENST00000395314 / NM_001271014.2; = p.A1073Gfs*15 on NM_004986.4) | Frame Shift Ins (INS) | VAF 34/248 reads (14%) | catalogued as rs1438655793; called by mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 29/259 reads (11%) | catalogued as rs747409331; called by mutect2, pindel, varscan2
- LCOR | c.2574dup p.E859Rfs*10 | Frame Shift Ins (INS) | VAF 37/256 reads (14%) | catalogued as rs1361355752; called by mutect2, varscan2
- LCOR | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs984753063; called by muse, mutect2, varscan2
- LENG8 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 133/715 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs373669476; called by muse, mutect2, varscan2
- LKAAEAR1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1244268776; called by muse, mutect2, varscan2
- LLGL2 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 94/602 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs769349711, COSV99389773; called by muse, mutect2, varscan2
- LONP2 | c.2275C>T p.R759W | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs754630302, COSV53522904; called by muse, mutect2, varscan2
- LONRF2 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773975682; called by muse, mutect2, varscan2
- LOXL4 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs373991076; called by muse, mutect2, varscan2
- LRP1 | c.6973G>A p.V2325I | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as rs765025195; called by muse, varscan2
- LRP1 | c.12721C>T p.R4241C | Missense Mutation (SNP) | VAF 78/433 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV54519558; called by muse, mutect2, varscan2
- LRP1B | c.12251G>A p.R4084H | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs756341470, COSV67226145, COSV67289058; called by muse, mutect2, varscan2
- LRRC36 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 42/245 reads (17%) | catalogued as rs772745615; called by muse, mutect2, varscan2
- LRRC3C | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 66/536 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs776989449; called by muse, varscan2
- LRSAM1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772739566; called by muse, mutect2, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 38/214 reads (18%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LVRN | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 62/476 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100773474, COSV63498653; called by muse, mutect2, varscan2
- LYPD2 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 84/577 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs149761941, COSV63649437; called by muse, mutect2, varscan2
- MAF | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.603); catalogued as COSV58153561; called by muse, mutect2, varscan2
- MAGEB17 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs757581615; called by muse, mutect2, varscan2
- MALRD1 | c.5962A>G p.N1988D | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1160084888; called by muse, varscan2
- MAN2C1 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs185465747; called by muse, mutect2, varscan2
- MAN2C1 | c.1738_1740del p.V580del | In Frame Del (DEL) | VAF 42/365 reads (12%) | catalogued as rs763199889; called by pindel, varscan2
- MAPK7 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as rs755374629, COSV100218969; called by muse, mutect2, varscan2
- MARF1 | c.4177G>A p.V1393M | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766558550, COSV60024207; called by muse, varscan2
- MATN2 | c.908G>A p.C303Y | Missense Mutation (SNP) | VAF 46/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1022985398; called by muse, mutect2, varscan2
- MCF2 | c.627del p.K209Nfs*4 | Frame Shift Del (DEL) | VAF 47/164 reads (29%) | catalogued as COSV58495248; called by mutect2, pindel, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 23/156 reads (15%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCTP2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs137927917, COSV59141943; called by muse, mutect2, varscan2
- MDC1 | c.549dup p.S184Ifs*14 | Frame Shift Ins (INS) | VAF 56/363 reads (15%) | catalogued as rs1185288475; called by mutect2, varscan2
- MDN1 | c.16043G>A p.R5348Q | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1401577967, COSV101021238; called by muse, mutect2, varscan2
- MECP2 | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs782644353; called by muse, mutect2, varscan2
- MED1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs201621617; called by muse, mutect2
- MED24 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as COSV62419463; called by muse, varscan2
- MEGF11 | c.2600G>A p.G867D | Missense Mutation (SNP) | VAF 39/630 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.298); catalogued as COSV56554232; called by muse, mutect2
- MGAM | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 46/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199504784; called by muse, mutect2, varscan2
- MGAM2 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 48/419 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.351); catalogued as rs1445465296; called by muse, mutect2, varscan2
- MLH3 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370545907; called by muse, mutect2, varscan2
- MMP2 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1477890644, COSV54601069; called by muse, mutect2, varscan2
- MORC2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1034098965; called by muse, mutect2, varscan2
- MOS | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 21/544 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs1421842842, COSV61336285; called by muse, mutect2
- MRGPRE | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 87/633 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs780072646, COSV67745476; called by muse, mutect2, varscan2
- MROH7 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.088); catalogued as rs750052987; called by muse, mutect2
- MRPL36 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV56875805; called by muse, mutect2, varscan2
- MRPS21 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 60/400 reads (15%) | catalogued as rs782772843; called by muse, mutect2
- MSL1 | c.1304G>A p.R435H (on ENST00000398532 / NM_001365919.1; = p.R172H on NM_001012241.2) | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.106); catalogued as rs201593396; called by muse, mutect2, varscan2
- MTMR3 | c.1813dup p.L605Pfs*8 | Frame Shift Ins (INS) | VAF 43/294 reads (15%) | catalogued as rs768299508; called by mutect2, varscan2
- MTNR1B | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99925333; called by muse, mutect2, varscan2
- MTOR | c.4918C>T p.R1640W | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs766533620, COSV63868467; called by muse, mutect2, varscan2
- MUC12 | c.2870C>A p.T957N (on ENST00000379442; = p.T814N on NM_001164462.1) | Missense Mutation (SNP) | VAF 73/1035 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.413); catalogued as rs201530219, COSV101059456; called by muse, mutect2
- MXD4 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1363301183; called by muse, mutect2, varscan2
- MYBPHL | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 45/504 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs779216234, COSV100848906; called by muse, mutect2
- MYH6 | c.1793del p.N598Tfs*63 | Frame Shift Del (DEL) | VAF 51/370 reads (14%) | catalogued as COSV100676665; called by mutect2, pindel, varscan2
- MYH6 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs1348513811, COSV62453206; called by muse, mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 24/206 reads (12%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO9B | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV68282385; called by muse, mutect2, varscan2
- MYT1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1042416220; called by muse, mutect2, varscan2
- NARF | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1013591686, COSV59112797; called by muse, varscan2
- NAV3 | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760922961, COSV57078990, COSV57117271; called by muse, varscan2
- NBEAL2 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1258088710; called by muse, mutect2, varscan2
- NCKAP1L | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769776941; called by muse, mutect2, varscan2
- NCKIPSD | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs138069597; called by muse, mutect2, varscan2
- NCOR2 | c.3178dup p.R1060Pfs*2 | Frame Shift Ins (INS) | VAF 62/512 reads (12%) | catalogued as rs749518211; called by mutect2, varscan2
- NEFM | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 59/474 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745446845; called by muse, mutect2, varscan2
- NFKBIB | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs759042553, COSV58005303; called by muse, mutect2, varscan2
- NFX1 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 19/638 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100582125; called by muse, mutect2
- NGF | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV65688511; called by muse, mutect2, varscan2
- NIPSNAP1 | c.362A>G p.Q121R | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.38); catalogued as rs780554208; called by muse, mutect2, varscan2
- NKX2-5 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 23/717 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV61298489; called by muse, mutect2
- NLRC4 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 63/329 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as rs1464761564, COSV99048592; called by muse, mutect2, varscan2
- NLRP11 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 25/313 reads (8%) | catalogued as COSV64086909; called by muse, mutect2
- NLRP7 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 110/730 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758384759, COSV60172527; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 40/296 reads (14%) | catalogued as rs751187638; called by mutect2, varscan2
- NOLC1 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 54/373 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs777960374; called by muse, mutect2, varscan2
- NOTCH2 | c.5512C>T p.R1838* | Nonsense Mutation (SNP) | VAF 42/389 reads (11%) | catalogued as rs766543218, COSV56688328; called by muse, mutect2, varscan2
- NOXO1 | c.589C>T p.R197W (on ENST00000397280 / NM_172168.3; = p.R191W on NM_144603.4) | Missense Mutation (SNP) | VAF 50/478 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1273049235; called by muse, mutect2, varscan2
- NPC1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 56/565 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs886053667, COSV52578608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPM2 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 93/358 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs753816878; called by muse, mutect2, varscan2
- NR1I3 | c.970C>T p.R324W (on ENST00000367982 / NM_001077480.3; = p.R320W on NM_005122.5) | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369817002, COSV100915553; called by muse, mutect2
- NR2E1 | c.1096dup p.T366Nfs*19 | Frame Shift Ins (INS) | VAF 32/252 reads (13%) | catalogued as rs1351659552; called by mutect2, varscan2
- NRDE2 | c.1008C>T p.D336= | Splice Region (SNP) | VAF 21/191 reads (11%) | catalogued as rs1309677230, COSV100583266; called by muse, mutect2, varscan2
- NUAK1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 71/447 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as rs117517173; called by muse, mutect2, varscan2
- NUDT5 | c.266del p.G89Afs*4 | Frame Shift Del (DEL) | VAF 42/345 reads (12%) | catalogued as rs1564424334; called by mutect2, pindel, varscan2
- NUFIP2 | c.670del p.R224Gfs*16 | Frame Shift Del (DEL) | VAF 54/427 reads (13%) | catalogued as rs772197760; called by mutect2, pindel, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 58/390 reads (15%) | catalogued as rs758695627; called by mutect2, varscan2
- NXF1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 65/367 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53674603; called by muse, mutect2, varscan2
- NYAP1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 80/616 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769864199; called by muse, mutect2, varscan2
- OBSCN | c.17894A>G p.D5965G | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99470678; called by mutect2, varscan2
- OPLAH | c.2708C>T p.A903V | Missense Mutation (SNP) | VAF 17/448 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.756); catalogued as rs560233274, COSV70677705; called by muse, mutect2
- OR10H4 | c.64del p.Q22Sfs*13 | Frame Shift Del (DEL) | VAF 80/364 reads (22%) | catalogued as COSV59061722; called by mutect2, pindel, varscan2
- OR2F2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 174/628 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371292578, COSV101283812; called by muse, mutect2, varscan2
- OR2S2 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 41/550 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV59529195; called by muse, mutect2
- OR2T12 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 66/396 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58777085; called by muse, mutect2
- OR4C11 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs746853721, COSV56353088; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 64/451 reads (14%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR8G5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.664); catalogued as rs148046413, COSV58383102; called by muse, mutect2, varscan2
- OSR2 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 56/512 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.026); catalogued as rs751081954, COSV52555649; called by muse, varscan2
- PAFAH1B3 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs774590864, COSV50546697; called by muse, mutect2, varscan2
- PAK5 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 69/533 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.033); catalogued as rs559720359, COSV62032667, COSV62039060; called by muse, mutect2, varscan2
- PAPLN | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752142488, COSV53715726; called by muse, mutect2, varscan2
- PAPLN | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 54/403 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1566673792; called by muse, mutect2, varscan2
- PAPPA2 | c.4085G>A p.R1362H | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768702466, COSV62802802, COSV62813164; called by muse, mutect2, varscan2
- PARD3B | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs771564394; called by muse, mutect2, varscan2
- PARS2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs140625560, COSV64883383; called by muse, mutect2
- PCDH11X | c.3846G>T p.W1282C | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV100008854; called by muse, mutect2
- PCDH18 | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766678974, COSV100787360, COSV61266240; called by muse, mutect2, varscan2
- PCDH7 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs759114908; called by muse, mutect2, varscan2
- PCDHA1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 64/428 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV65374886; called by muse, mutect2, varscan2
- PCDHA13 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 60/644 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs782029001, COSV99165119; called by muse, mutect2
- PCDHA4 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 70/451 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.042); catalogued as rs76650315; called by muse, mutect2, varscan2
- PCDHAC1 | c.1852C>T p.L618F | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs143875858, COSV53836588; called by muse, mutect2, varscan2
- PCDHB13 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 91/603 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53400502; called by muse, mutect2, varscan2
- PCDHB2 | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as COSV50640568; called by muse, mutect2
- PCDHGA12 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 120/756 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.166); catalogued as COSV52743421; called by muse, mutect2, varscan2
- PCDHGA7 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99546183; called by muse, mutect2, varscan2
- PCDHGA7 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 74/513 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); catalogued as rs762319044, COSV99534637; called by muse, mutect2, varscan2
- PCMTD1 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs767756923, COSV62119286; called by muse, mutect2, varscan2
- PCNX1 | c.2882G>A p.G961D | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs759807930; called by muse, mutect2, varscan2
- PCSK6 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371571940, COSV59343811; called by muse, mutect2, varscan2
- PDE2A | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1240732900; called by muse, varscan2
- PDE4D | c.1909C>T p.R637W (on ENST00000340635 / NM_001104631.2; = p.R501W on NM_006203.4) | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as rs775209507; called by muse, mutect2, varscan2
- PDE6C | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs376438891, COSV101008524; called by muse, varscan2
- PEX10 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 70/529 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs368143757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PFKFB4 | c.748del p.R250Afs*36 | Frame Shift Del (DEL) | VAF 89/483 reads (18%) | catalogued as rs1560163676, COSV51680585; called by mutect2, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 34/212 reads (16%) | catalogued as rs1161592176; called by mutect2, pindel, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 37/230 reads (16%) | catalogued as rs770560794; called by mutect2, varscan2
- PHYKPL | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs772375595, COSV100359488; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 26/174 reads (15%) | catalogued as rs756552559; called by mutect2, varscan2
- PIGN | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 49/401 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1384644095, COSV100715918, COSV62948300; called by muse, mutect2, varscan2
- PIGN | c.1494dup p.L499Sfs*58 | Frame Shift Ins (INS) | VAF 50/445 reads (11%) | catalogued as rs750418747; called by mutect2, pindel, varscan2
- PIK3R5 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344760998; called by muse, mutect2, varscan2
- PITPNM1 | c.2879C>T p.T960M | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs371845321; called by muse, mutect2, varscan2
- PKD1 | c.6329C>T p.A2110V | Missense Mutation (SNP) | VAF 104/590 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.422); catalogued as rs1266395140; called by muse, mutect2, varscan2
- PKP2 | c.2612G>A p.R871Q | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs372263407, COSV50753395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCG2 | c.3601C>T p.R1201C | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs761018891; called by muse, mutect2, varscan2
- PLEKHA2 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1318135701, COSV56759279; called by muse, mutect2
- PLEKHA7 | c.3271C>T p.R1091C | Missense Mutation (SNP) | VAF 74/460 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761822621; called by muse, mutect2, varscan2
- PLEKHH3 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 93/560 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV53190945; called by muse, mutect2, varscan2
- PLP2 | c.81_83del p.L28del | In Frame Del (DEL) | VAF 45/186 reads (24%) | catalogued as rs782804665; called by pindel, varscan2
- PLTP | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.154); catalogued as rs1333750200; called by muse, mutect2
- PMFBP1 | c.1915G>A p.E639K (on ENST00000537465; = p.E634K on NM_031293.3) | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV52821958; called by muse, mutect2
- POC1B-GALNT4 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs762476727; called by muse, mutect2, varscan2
- POGLUT3 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 38/321 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs748708642; called by muse, mutect2, varscan2
- POLL | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 79/470 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745476164; called by muse, mutect2, varscan2
- POLRMT | c.2863G>A p.V955M | Missense Mutation (SNP) | VAF 43/367 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207882477; called by muse, mutect2, varscan2
- POLRMT | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 108/566 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754938918, COSV52115548; called by muse, mutect2, varscan2
- POMT2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 63/374 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs756055923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POR | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 78/604 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs782215859; called by muse, mutect2, varscan2
- POU4F2 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 82/534 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV99850634; called by muse, varscan2
- PPP1R12A | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs556820145; called by muse, mutect2, varscan2
- PPP1R26 | c.3161del p.G1054Afs*100 | Frame Shift Del (DEL) | VAF 80/546 reads (15%) | catalogued as rs1554733377; called by mutect2, varscan2
- PPP2R3B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 80/706 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1273147752, COSV66814125; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | catalogued as rs540232176; called by mutect2, varscan2
- PPWD1 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 28/251 reads (11%) | catalogued as rs1203891120; called by muse, mutect2, varscan2
- PRADC1 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375821182; called by muse, mutect2, varscan2
- PRKACA | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100431762; called by muse, mutect2, varscan2
- PRKCSH | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs759778147, COSV52952285; called by muse, mutect2, varscan2
- PRKDC | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as rs1245428623, COSV100040519; called by muse, mutect2
- PRKX | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.098); catalogued as rs900159954; called by muse, mutect2, varscan2
- PRLHR | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 82/629 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs1328613305, COSV53302763; called by muse, mutect2, varscan2
- PROB1 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 86/463 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1172467483, COSV56172711; called by muse, mutect2, varscan2
- PRPF4 | c.571C>T p.R191C (on ENST00000374198 / NM_001322267.2; = p.R192C on NM_004697.5) | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100950783; called by muse, mutect2, varscan2
- PRSS36 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 138/707 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs1328790557, COSV51636829; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 30/226 reads (13%) | catalogued as COSV101122574; called by mutect2, varscan2
- PSRC1 | c.1009C>T p.R337* (on ENST00000409138 / NM_001363309.1; = p.R307* on NM_032636.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/358 reads (17%) | catalogued as rs779017765; called by muse, mutect2, varscan2
- PTCH1 | c.3936G>A p.W1312* | Nonsense Mutation (SNP) | VAF 74/645 reads (11%) | catalogued as COSV59477211; called by muse, mutect2, varscan2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 26/168 reads (15%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PTK6 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.721); catalogued as rs757639084; called by muse, mutect2, varscan2
- PTPN13 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 37/297 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373380309; called by muse, mutect2, varscan2
- PTPN4 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55310509, COSV99751845; called by muse, mutect2, varscan2
- PTPN7 | c.206A>G p.E69G (on ENST00000495688; = p.E108G on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/437 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58311452; called by muse, mutect2, varscan2
- PTPRJ | c.2528G>A p.S843N | Missense Mutation (SNP) | VAF 58/322 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.796); catalogued as rs760930507; called by muse, mutect2, varscan2
- PTPRJ | c.4006A>G p.I1336V | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.754); catalogued as rs1483126559; called by muse, mutect2, varscan2
- PTPRM | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 42/339 reads (12%) | catalogued as COSV59880315; called by muse, mutect2, varscan2
- PTPRU | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 62/508 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200344921, COSV60522024; called by muse, mutect2, varscan2
- PWWP3B | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1458248044; called by muse, mutect2, varscan2
- QSOX1 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 81/458 reads (18%) | catalogued as rs1422113978; called by muse, mutect2, varscan2
- RAB40C | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs145997805; called by muse, mutect2, varscan2
- RAB5C | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs780114908, COSV60524338; called by muse, mutect2, varscan2
- RAI1 | c.2363C>T p.S788L | Missense Mutation (SNP) | VAF 99/468 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.06); catalogued as rs761594217, COSV99885062; called by muse, varscan2
- RAPGEF2 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 49/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768834451; called by muse, mutect2, varscan2
- RBM12B | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 165/551 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.353); catalogued as rs775955349; called by muse, mutect2, varscan2
- RBM47 | c.1477G>A p.A493T (on ENST00000295971 / NM_001098634.2; = p.A424T on NM_019027.4) | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.985); catalogued as rs748134090, COSV55931549; called by muse, varscan2
- RC3H2 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.108); catalogued as rs368828068, COSV61801537; called by muse, mutect2, varscan2
- RCN3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 108/640 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1232284690, COSV54542636; called by muse, mutect2, varscan2
- RELN | c.252del p.F84Lfs*6 | Frame Shift Del (DEL) | VAF 38/293 reads (13%) | catalogued as rs1563089897; called by mutect2, pindel, varscan2
- RFX3 | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100174907; called by muse, mutect2, varscan2
- RLF | c.4255del p.Y1419Ifs*6 | Frame Shift Del (DEL) | VAF 44/340 reads (13%) | catalogued as COSV65652466; called by mutect2, pindel, varscan2
- RND2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 74/406 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs773244091; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF31 | c.1336dup p.R446Pfs*21 | Frame Shift Ins (INS) | VAF 48/434 reads (11%) | catalogued as rs758350558; called by mutect2, pindel
- RNF34 | c.472_474del p.D158del | In Frame Del (DEL) | VAF 56/390 reads (14%) | catalogued as rs782395706; called by pindel, varscan2
- RNPS1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 48/360 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.973); catalogued as COSV57046550; called by muse, mutect2, varscan2
- ROBO4 | c.32del p.G11Afs*25 | Frame Shift Del (DEL) | VAF 52/394 reads (13%) | catalogued as rs781111238; called by mutect2, pindel, varscan2
- ROR2 | c.2467G>A p.G823S | Missense Mutation (SNP) | VAF 54/654 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs753371692; called by muse, mutect2
- RP1L1 | c.7096G>A p.A2366T | Missense Mutation (SNP) | VAF 72/452 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV66754383; called by muse, mutect2, varscan2
- RPL3 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs755263201, COSV53364611; called by muse, mutect2, varscan2
- RPL7A | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs1383551075; called by muse, mutect2, varscan2
- RTN1 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 43/309 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50745713; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 35/266 reads (13%) | catalogued as rs761969807; called by mutect2, varscan2
- RUSC2 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 87/655 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs199600309; called by muse, mutect2, varscan2
- RUSC2 | c.3449C>A p.P1150H | Missense Mutation (SNP) | VAF 69/530 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs748199369; called by muse, mutect2, varscan2
- RUVBL1 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59477433; called by muse, mutect2
- RUVBL2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs780895064; called by muse, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 79/666 reads (12%) | catalogued as rs761606832; called by mutect2, pindel, varscan2
- SCN1A | c.2243G>T p.W748L (on ENST00000303395 / NM_001202435.3; = p.W737L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM1211370; called by mutect2, varscan2
- SCYL3 | c.2108del p.K703Rfs*7 (on ENST00000367770; = p.K649Rfs*7 on NM_020423.7) | Frame Shift Del (DEL) | VAF 52/321 reads (16%) | catalogued as rs1558112386; called by mutect2, pindel, varscan2
- SDK2 | c.2072C>T p.T691M | Missense Mutation (SNP) | VAF 59/341 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs756473256, COSV66188801; called by muse, varscan2
- SEC63 | c.1596A>T p.L532F | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs756336859, COSV64598351, COSV64602524; called by muse, varscan2
- SELENOO | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 33/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1437569574; called by muse, mutect2
- SEPTIN3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs200659820; called by muse, mutect2, varscan2
- SERPINB12 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1482989488; called by muse, mutect2, varscan2
- SETD7 | c.147del p.K50Sfs*38 | Frame Shift Del (DEL) | VAF 49/270 reads (18%) | catalogued as COSV99918469; called by mutect2, pindel, varscan2
- SETX | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 61/441 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777182592, COSV56394115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SF3B2 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1200427050, COSV59427603; called by muse, mutect2, varscan2
- SFSWAP | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1322718182, COSV55520068; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 36/222 reads (16%) | catalogued as rs1260834379; called by mutect2, varscan2
- SH2B1 | c.1534del p.E512Sfs*31 | Frame Shift Del (DEL) | VAF 57/374 reads (15%) | catalogued as rs1410542268; called by mutect2, pindel, varscan2
- SH2D4B | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 25/217 reads (12%) | catalogued as rs564378251; called by muse, mutect2, varscan2
- SH3BP5L | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759773883; called by muse, mutect2, varscan2
- SH3D19 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 52/296 reads (18%) | catalogued as rs373289881; called by muse, mutect2, varscan2
- SH3RF3 | c.1519C>A p.L507M | Missense Mutation (SNP) | VAF 64/386 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.402); catalogued as COSV58695190, COSV99079872; called by muse, mutect2, varscan2
- SHC3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1444894101; called by muse, mutect2
- SHOC1 | c.4333del p.*1445Efs*45 | Frame Shift Del (DEL) | VAF 27/231 reads (12%) | catalogued as rs769088263; called by mutect2, pindel, varscan2
- SHROOM2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as rs192496291; called by muse, mutect2, varscan2
- SIL1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs202053975, COSV54535311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIM1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1450063558; called by muse, mutect2, varscan2
- SLC10A2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99808122; called by muse, mutect2
- SLC12A9 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 86/606 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.069); catalogued as rs780475643; called by muse, mutect2, varscan2
- SLC16A11 | c.1069G>A p.A357T (on ENST00000308009; = p.A333T on NM_153357.3) | Missense Mutation (SNP) | VAF 90/653 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV57273931; called by muse, mutect2, varscan2
- SLC18A3 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 93/587 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100340211; called by muse, mutect2, varscan2
- SLC22A24 | c.1447G>C p.A483P | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as rs1366680010; called by muse, mutect2
- SLC23A2 | c.1789G>A p.G597S | Missense Mutation (SNP) | VAF 63/434 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761611509, COSV57772790, COSV57774719; called by muse, mutect2, varscan2
- SLC25A13 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs199744651, COSV55706361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A31 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs769144214; called by muse, mutect2, varscan2
- SLC25A35 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs957136739; called by muse, mutect2, varscan2
- SLC25A36 | c.795del p.Q266Rfs*19 (on ENST00000324194 / NM_001104647.3; = p.Q265Rfs*19 on NM_018155.3) | Frame Shift Del (DEL) | VAF 26/204 reads (13%) | catalogued as rs1559818665; called by mutect2, pindel, varscan2
- SLC29A1 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1440830776; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 31/212 reads (15%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC47A2 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 61/400 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs113234335, COSV51565603; called by muse, varscan2
- SLC8A1 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV60479849; called by muse, mutect2, varscan2
- SMARCD2 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 48/310 reads (15%) | catalogued as rs367946883, COSV56739479; called by muse, mutect2, varscan2
- SMCHD1 | c.2040del p.K680Nfs*3 | Frame Shift Del (DEL) | VAF 33/287 reads (11%) | catalogued as rs766211852; called by mutect2, pindel, varscan2
- SMG1 | c.6052G>A p.V2018I | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs748691778, COSV67171754; called by muse, mutect2, varscan2
- SNX13 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 29/517 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1453703804, COSV68063960; called by muse, mutect2
- SOCS5 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 68/413 reads (16%) | catalogued as COSV60604139; called by muse, mutect2, varscan2
- SORBS3 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 61/357 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368264093; called by muse, varscan2
- SORCS3 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 96/600 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs1251985956; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 33/274 reads (12%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOS1 | c.1844A>G p.Y615C | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101217352; called by muse, mutect2, varscan2
- SOS2 | c.2784del p.F928Lfs*5 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | catalogued as rs1347298671; called by mutect2, varscan2
- SOX1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 57/461 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1427558069; called by muse, mutect2, varscan2
- SOX8 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 108/600 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs779574372, COSV53510080; called by muse, mutect2, varscan2
- SPATS2L | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as rs941224112; called by muse, mutect2, varscan2
- SPCS1 | c.292dup p.S98Ffs*13 (on ENST00000233025; = p.S31Ffs*13 on NM_014041.5) | Frame Shift Ins (INS) | VAF 36/315 reads (11%) | catalogued as rs754517312; called by mutect2, pindel, varscan2
- SPDYE1 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 75/638 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs142373103; called by muse, mutect2, varscan2
- SPRTN | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766305995, COSV50477503; called by muse, mutect2, varscan2
- SPTB | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 51/371 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs201849832, COSV101072234, COSV67630352; called by muse, mutect2, varscan2
- SPTBN2 | c.3782A>G p.K1261R | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs371145706; called by muse, mutect2
- SRCAP | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1215453424, COSV99349922; called by muse, varscan2
- SRPK2 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 66/455 reads (15%) | catalogued as rs1437515182, COSV61959637; called by muse, mutect2, varscan2
- SRRT | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763989148, COSV100730056, COSV61453585; called by muse, mutect2, varscan2
- SSC4D | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 80/703 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs770061203, COSV51882151; called by muse, mutect2, varscan2
- SSC5D | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 81/529 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs546865552, COSV101046892; called by muse, mutect2, varscan2
- SSRP1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 19/442 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV53480567; called by muse, mutect2
- SSTR1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 52/387 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV57457171; called by muse, mutect2, varscan2
- SSTR5 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 83/615 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs369907643; called by muse, mutect2, varscan2
- ST8SIA1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.2); catalogued as rs774559978; called by muse, mutect2, varscan2
- STIL | c.3568G>A p.A1190T | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139856969; called by muse, mutect2, varscan2
- STK10 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.058); catalogued as rs563239491, COSV51577046; called by muse, mutect2, varscan2
- STMN4 | c.497G>A p.R166Q (on ENST00000265770 / NM_001283054.2; = p.R193Q on NM_030795.4) | Missense Mutation (SNP) | VAF 41/602 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56110360; called by muse, mutect2
- STOX1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53813466; called by muse, mutect2, varscan2
- STRC | c.4804C>T p.R1602W | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs370775837; called by muse, mutect2, varscan2
- STT3B | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as CM142613, COSV99854604; called by muse, mutect2
- SULT6B1 | c.257dup p.Y87Vfs*2 (on ENST00000535679 / NM_001367551.1; = p.Y49Vfs*2 on NM_001032377.2) | Frame Shift Ins (INS) | VAF 34/170 reads (20%) | catalogued as rs747003550; called by mutect2, varscan2
- SUPT16H | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV53524273; called by muse, mutect2
- SVOP | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs868450077; called by muse, mutect2, varscan2
- SYDE2 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.92); catalogued as rs946899293, COSV52314878; called by muse, mutect2, varscan2
- SYN1 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs760401568, COSV54482968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE3 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as rs549347311; called by muse, mutect2, varscan2
- SYNJ2BP | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746785753; called by muse, mutect2, varscan2
- SYT3 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 69/478 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866886368; called by muse, mutect2, varscan2
- TACR3 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1195516345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF15 | c.1768C>T p.R590* (on ENST00000605844 / NM_139215.3; = p.R587* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 55/403 reads (14%) | catalogued as rs376443844; called by muse, mutect2, varscan2
- TAS1R1 | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 61/467 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.264); catalogued as rs760042477; called by muse, mutect2, varscan2
- TBC1D20 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs774126724; called by muse, mutect2, varscan2
- TBC1D9B | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 61/442 reads (14%) | catalogued as rs199992645, COSV62284081; called by muse, mutect2, varscan2
- TBCEL | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52462814; called by muse, mutect2, varscan2
- TBL1X | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs142521703; called by mutect2, varscan2
- TBL2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 57/484 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782361220, COSV99979696; called by muse, mutect2, varscan2
- TBR1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV67419275; called by muse, mutect2, varscan2
- TCAF2 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.387); catalogued as rs1419545737; called by muse, mutect2, varscan2
- TECTA | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 66/466 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV50717891, COSV99880636; called by muse, mutect2, varscan2
- TECTB | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs749582234, COSV65596470; called by muse, mutect2, varscan2
- TEDC2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 72/585 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751698804, COSV99563751; called by muse, mutect2, varscan2
- TENM3 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1397875171; called by muse, mutect2, varscan2
- TEX2 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs782705677, COSV51983176, COSV51983754; called by muse, mutect2, varscan2
- TFAP4 | c.590T>A p.L197Q | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52597703; called by mutect2, varscan2
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 21/219 reads (10%) | catalogued as rs771133493, COSV55406589; called by mutect2, pindel, varscan2
- TGM1 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199786703, COSV52865179; called by muse, mutect2, varscan2
- TGOLN2 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.961); catalogued as rs867917754; called by muse, mutect2, varscan2
- THAP12 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs756630094; called by muse, mutect2, varscan2
- THAP5 | c.297del p.K99Nfs*25 (on ENST00000415914 / NM_001130475.3; = p.K57Nfs*25 on NM_182529.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/224 reads (24%) | catalogued as rs745348876; called by mutect2, varscan2
- THBS1 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV99527715; called by muse, mutect2, varscan2
- TKT | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs782403023; called by muse, mutect2, varscan2
- TLE1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 83/645 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as rs556195256, COSV64689876; called by muse, mutect2, varscan2
- TLR4 | c.973G>T p.D325Y (on ENST00000355622 / NM_138554.5; = p.D285Y on NM_003266.4) | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62922415, COSV62922723; called by muse, mutect2, varscan2
- TLX2 | c.292del p.A98Rfs*16 | Frame Shift Del (DEL) | VAF 104/681 reads (15%) | catalogued as rs1238341034; called by mutect2, pindel, varscan2
- TMC4 | c.1271G>A p.R424H (on ENST00000617472 / NM_001145303.3; = p.R418H on NM_144686.4) | Missense Mutation (SNP) | VAF 18/445 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV55827881; called by muse, mutect2
- TMEM116 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 28/283 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244051032; called by muse, mutect2
- TMEM163 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as rs755523021, COSV56110820; called by muse, mutect2, varscan2
- TMEM198 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 115/621 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs768767598; called by muse, mutect2, varscan2
- TMEM255B | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs199895059; called by muse, mutect2, varscan2
- TMEM63B | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs781648674; called by muse, mutect2, varscan2
- TMPRSS6 | c.22del p.Q8Rfs*60 | Frame Shift Del (DEL) | VAF 72/489 reads (15%) | catalogued as rs759084210; called by mutect2, pindel, varscan2
- TMX3 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV55184901; called by muse, mutect2, varscan2
- TNFRSF18 | c.298del p.V100Yfs*67 | Frame Shift Del (DEL) | VAF 52/313 reads (17%) | catalogued as rs773489494; called by mutect2, pindel, varscan2
- TNFRSF21 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 87/494 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs888086780; called by muse, mutect2, varscan2
- TNKS | c.1109C>A p.S370* | Nonsense Mutation (SNP) | VAF 12/186 reads (6%) | catalogued as COSV60057741; called by muse, mutect2
- TNNI3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs374618872; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TNRC18 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 72/452 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs758078517, COSV68164795; called by muse, varscan2
- TOX2 | c.1066G>A p.A356T (on ENST00000358131 / NM_001098798.2; = p.A332T on NM_032883.3) | Missense Mutation (SNP) | VAF 81/693 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as rs748629118; called by muse, varscan2
- TP53BP1 | c.5215G>A p.A1739T | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1045342080; called by muse, mutect2, varscan2
- TP53BP1 | c.2993C>T p.A998V | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV55500458; called by muse, mutect2, varscan2
- TPRA1 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 79/556 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1044485311; called by muse, mutect2, varscan2
- TRAP1 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766273732; called by muse, mutect2, varscan2
- TRAPPC6A | c.280G>A p.V94I (on ENST00000585934 / NM_001270891.2; = p.V108I on NM_024108.3) | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs752910934; called by muse, mutect2, varscan2
- TRAPPC9 | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 27/399 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773583681; called by muse, mutect2
- TRIM17 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 40/303 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs759807141, COSV52856600; called by muse, mutect2, varscan2
- TRIM41 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 79/473 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs954326574; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 28/190 reads (15%) | catalogued as rs763121810; called by mutect2, varscan2
- TRIM54 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 71/444 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as rs756247733, COSV56084224; called by muse, mutect2, varscan2
- TRPM3 | c.4519C>T p.R1507C (on ENST00000357533 / NM_001366142.2; = p.R1362C on NM_020952.6) | Missense Mutation (SNP) | VAF 67/479 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1035251103, COSV62596606; called by muse, mutect2, varscan2
- TRPM3 | c.3806C>T p.T1269M (on ENST00000357533 / NM_001366142.2; = p.T1124M on NM_020952.6) | Missense Mutation (SNP) | VAF 70/526 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs142899826; called by muse, mutect2, varscan2
- TRPS1 | c.758G>A p.R253H (on ENST00000220888 / NM_001330599.2; = p.R266H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/430 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1410987986, COSV55252462; called by muse, varscan2
- TTC34 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 90/587 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs113477241; called by muse, mutect2, varscan2
- TTC4 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.052); catalogued as rs568822325; called by muse, mutect2, varscan2
- TTC5 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99352036; called by muse, mutect2, varscan2
- TTLL13P | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs371974190; called by muse, mutect2, varscan2
- TTN | c.86237C>T p.T28746I (on ENST00000591111; = p.T21322I on NM_003319.4) | Missense Mutation (SNP) | VAF 57/413 reads (14%) | PolyPhen benign (0.005); catalogued as rs754591100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.58406C>T p.A19469V (on ENST00000591111; = p.A12045V on NM_003319.4) | Missense Mutation (SNP) | VAF 46/307 reads (15%) | PolyPhen benign (0.035); catalogued as rs370687831; ClinVar: benign / likely benign / uncertain significance; called by muse, varscan2
- TTN | c.2219G>A p.R740H (on ENST00000591111; = p.R694H on NM_003319.4) | Missense Mutation (SNP) | VAF 54/354 reads (15%) | PolyPhen benign (0); catalogued as rs28933405, CM993514, COSV60026825; called by muse, mutect2, varscan2
- TUBB4A | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 201/594 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); catalogued as rs756958534; called by muse, mutect2, varscan2
- TUBGCP5 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 76/543 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs745662165; called by muse, mutect2, varscan2
- TYRO3 | c.2326C>T p.R776C | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55480871; called by muse, mutect2
- U2SURP | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67532941; called by muse, mutect2
- UACA | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs530685196; called by muse, mutect2, varscan2
- UGT1A5 | c.224del p.F75Sfs*3 | Frame Shift Del (DEL) | VAF 42/306 reads (14%) | catalogued as COSV100529395; called by mutect2, pindel, varscan2
- UGT1A9 | c.364del p.S122Qfs*12 | Frame Shift Del (DEL) | VAF 45/271 reads (17%) | catalogued as rs773627969; called by mutect2, varscan2
- ULBP1 | c.522_524del p.K174del | In Frame Del (DEL) | VAF 46/296 reads (16%) | catalogued as rs756161290; called by pindel, varscan2
- UNC13C | c.3945A>C p.E1315D | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV52847570, COSV99524809; called by muse, varscan2
- UPF1 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 57/439 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99439460; called by muse, mutect2, varscan2
- USP12 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as COSV99997637; called by muse, mutect2, varscan2
- VARS1 | c.613G>T p.G205* | Nonsense Mutation (SNP) | VAF 54/428 reads (13%) | catalogued as COSV100989530; called by muse, mutect2, varscan2
- VAX1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 83/526 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370078092; called by muse, mutect2, varscan2
- VEGFD | c.589del p.R197Afs*66 | Frame Shift Del (DEL) | VAF 45/179 reads (25%) | catalogued as COSV52909186; called by mutect2, pindel, varscan2
- VPS35L | c.841T>G p.F281V | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51988943; called by muse, varscan2
- VRTN | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs747084343; called by muse, mutect2, varscan2
- VSIG10L | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1187455444, COSV99570702; called by muse, mutect2, varscan2
- VSTM4 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs754188950; called by muse, mutect2, varscan2
- WDFY4 | c.440T>A p.L147H | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217424599; called by muse, mutect2, varscan2
- WDR59 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1342952465, COSV50936987; called by muse, mutect2, varscan2
- WDR90 | c.2623G>A p.G875S | Missense Mutation (SNP) | VAF 50/366 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs578038949, COSV53472217; called by muse, mutect2, varscan2
- WDR90 | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 73/605 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as rs1439915428; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 37/201 reads (18%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFS1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs375904080, CM134079; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WFS1 | c.722A>G p.Y241C | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1174592876; called by muse, mutect2, varscan2
- WHRN | c.2219C>T p.A740V | Missense Mutation (SNP) | VAF 64/406 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.388); catalogued as rs976736112, COSV54332894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT5A | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 79/506 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV52838981; called by muse, mutect2, varscan2
- WRAP73 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs753929735; called by muse, varscan2
- YWHAB | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.19); catalogued as rs1386279474; called by muse, mutect2, varscan2
- ZBED1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 114/683 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs376848620; called by muse, mutect2, varscan2
- ZBED5 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT tolerated, low confidence (0.74); PolyPhen possibly damaging (0.908); catalogued as rs1358641960; called by muse, mutect2, varscan2
- ZEB2 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs730881194, COSV100356718, COSV57953987; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZFHX3 | c.5677A>G p.R1893G | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1465596056; called by mutect2, varscan2
- ZFHX4 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 19/467 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); catalogued as rs1050373982, COSV51473220; called by muse, mutect2
- ZFHX4 | c.9230C>T p.T3077M | Missense Mutation (SNP) | VAF 96/345 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs377249680; called by muse, varscan2
- ZFP14 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.297); catalogued as rs1432542012; called by muse, mutect2, varscan2
- ZFP36L2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 86/608 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1346087275; called by muse, mutect2, varscan2
- ZFP92 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV58599012; called by muse, mutect2, varscan2
- ZFR2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs773375916, COSV99507341; called by muse, varscan2
- ZFX | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1471539862; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF219 | c.2157dup p.Q720Afs*13 | Frame Shift Ins (INS) | VAF 56/365 reads (15%) | catalogued as rs771569784; called by mutect2, varscan2
- ZNF226 | c.768G>T p.E256D | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs777265407; called by muse, mutect2, varscan2
- ZNF264 | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54042422; called by muse, mutect2, varscan2
- ZNF281 | c.1958G>A p.G653D | Missense Mutation (SNP) | VAF 19/414 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54167120; called by muse, mutect2
- ZNF292 | c.6280C>T p.R2094* | Nonsense Mutation (SNP) | VAF 55/360 reads (15%) | catalogued as COSV100370983; called by muse, mutect2, varscan2
- ZNF324 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 69/516 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs759150950, COSV99543047; called by muse, mutect2, varscan2
- ZNF324B | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 102/707 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as rs773602687, COSV60741356; called by muse, mutect2, varscan2
- ZNF330 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as rs1172108916; called by muse, mutect2, varscan2
- ZNF335 | c.3934G>T p.G1312C | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100533538; called by muse, mutect2, varscan2
- ZNF341 | c.2189G>A p.R730H (on ENST00000375200 / NM_001282935.1; = p.R723H on NM_032819.4) | Missense Mutation (SNP) | VAF 72/736 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs773489613; called by muse, mutect2
- ZNF425 | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 83/564 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV65201432; called by muse, mutect2, varscan2
- ZNF442 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs139605905; called by muse, mutect2, varscan2
- ZNF467 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 94/741 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs895885304, COSV57371854, COSV57373245; called by muse, mutect2, varscan2
- ZNF467 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 128/896 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100117740; called by muse, mutect2
- ZNF469 | c.2714C>T p.T905M | Missense Mutation (SNP) | VAF 96/596 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.849); catalogued as rs1401154628; called by muse, mutect2, varscan2
- ZNF521 | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 60/502 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs1021240858; called by muse, mutect2, varscan2
- ZNF532 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 78/541 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as rs370955739, COSV60172026; called by muse, mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 21/219 reads (10%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF548 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs377304568; called by muse, mutect2, varscan2
1,109 further variants in this file (596 protein-altering or splice-affecting, 440 silent, 73 other) are not listed here.
